Somatic mutation profile of tumor specimen TCGA-06-0238-01A (aliquot TCGA-06-0238-01A-02D-1492-08) from TCGA case TCGA-06-0238, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 46.6 years (17,037 days).
Specimen TCGA-06-0238-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 694a1727-5352-4975-bc43-4e6f1ca67c2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0238-10A (Blood Derived Normal), aliquot TCGA-06-0238-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c10d784f-5c6d-49c2-ac73-fdc65efbcdb3

The open-access MAF lists 43 somatic variants for this specimen: 37 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 5, Nonsense Mutation 1, Frame Shift Ins 1, Frame Shift Del 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.715_723del p.N239_S241del | In Frame Del (DEL) | VAF 24/53 reads (45%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ASZ1 | c.650T>C p.M217T | Missense Mutation (SNP) | VAF 58/273 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52916926; called by muse, mutect2, varscan2
- CASP1 | c.811C>T p.P271S (on ENST00000436863 / NM_033292.4; = p.P250S on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.172); catalogued as rs1028235018, COSV62057629; called by muse, mutect2, varscan2
- DAXX | c.1759T>C p.S587P | Missense Mutation (SNP) | VAF 73/166 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV56473349; called by muse, mutect2, varscan2
- DDIT3 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 238/754 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV56259210; called by muse, mutect2, varscan2
- IGHV1-18 | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 111/364 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as rs782521604; called by muse, mutect2, varscan2
- IWS1 | c.2359C>T p.R787* | Nonsense Mutation (SNP) | VAF 61/142 reads (43%) | catalogued as rs1294357446, COSV54869896; called by muse, mutect2, varscan2
- KEL | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs150577967; called by muse, mutect2, varscan2
- KPRP | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs973386436, COSV64223149; called by muse, mutect2, varscan2
- MAP3K15 | c.1687C>A p.P563T | Missense Mutation (SNP) | VAF 135/198 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV58840036; called by muse, mutect2, varscan2
- NLRP2 | c.1441C>T p.R481C | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs770750785, COSV54752800; called by muse, mutect2, varscan2
- NOTCH3 | c.1642G>A p.D548N | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.05); catalogued as rs1019920355, COSV54648551; called by muse, mutect2, varscan2
- OR10Z1 | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 139/397 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs191031344; called by muse, mutect2, varscan2
- OR2T34 | c.307G>T p.G103W | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60902212; called by muse, mutect2, varscan2
- OR5P2 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 82/195 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs748657480, COSV61490357; called by muse, mutect2, varscan2
- PCDHGA2 | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 65/216 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as COSV53932869; called by muse, mutect2, varscan2
- PCNX1 | c.3502A>C p.I1168L | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53103390; called by muse, mutect2, varscan2
- PIP4K2C | c.865G>T p.D289Y | Missense Mutation (SNP) | VAF 368/5412 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61605728, COSV61607084; called by muse, mutect2
- PIP4K2C | c.1068C>G p.I356M | Missense Mutation (SNP) | VAF 118/1753 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.457); catalogued as COSV61606028, COSV61607087; called by muse, mutect2
- PTCD2 | c.371A>G p.N124S | Missense Mutation (SNP) | VAF 13/401 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.077); catalogued as COSV57339429; called by muse, mutect2
- RSL1D1 | c.1427C>A p.T476N | Missense Mutation (SNP) | VAF 146/416 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); catalogued as COSV63077884, COSV63078630; called by muse, mutect2, varscan2
- SPATA31D1 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs267602287, COSV61193328; called by muse, mutect2, varscan2
- SPTA1 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 71/190 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63753042; called by muse, mutect2, varscan2
- SV2C | c.545A>G p.D182G | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV59230453; called by muse, mutect2
- TEKT4 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as rs544727913; called by muse, mutect2, varscan2
- TENM2 | c.3392C>G p.A1131G (on ENST00000518659 / NM_001122679.2; = p.A899G on NM_001080428.3) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101317768, COSV69143717; called by muse, mutect2, varscan2
- TFPI2 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs767746862, COSV55991088; called by muse, mutect2, varscan2
- TJP1 | c.4256A>G p.Y1419C | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs200549140, COSV62039438; called by muse, mutect2, varscan2
- TMEM41B | c.826T>C p.S276P | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.701); catalogued as COSV55157104; called by muse, mutect2
- TPTE2 | c.114T>A p.S38R | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.08); catalogued as COSV55029555; called by muse, mutect2, varscan2
- TSPAN31 | c.374G>A p.R125K | Missense Mutation (SNP) | VAF 35/1120 reads (3%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV57277380; called by muse, mutect2
- UBE3D | c.880del p.E294Nfs*3 | Frame Shift Del (DEL) | VAF 40/117 reads (34%) | catalogued as COSV52758367; called by mutect2, pindel, varscan2
- ZNF317 | c.1298T>A p.L433H | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56111808; called by muse, mutect2, varscan2
- ZNF618 | c.814C>A p.Q272K (on ENST00000374126 / NM_001318042.2; = p.Q260K on NM_133374.2) | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV55931084; called by muse, mutect2, varscan2
- FCGBP | c.3299G>A p.G1100D | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KIAA1614 | c.2159G>C p.G720A | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.046); called by muse, mutect2
- UQCRQ | c.130dup p.E44Gfs*22 | Frame Shift Ins (INS) | VAF 25/92 reads (27%) | called by mutect2, pindel, varscan2
- PCDH7 | c.2826A>G p.K942= | Silent (SNP) | VAF 50/124 reads (40%) | catalogued as COSV62344173; called by muse, mutect2, varscan2
- PCDHA1 | c.1746G>A p.P582= | Silent (SNP) | VAF 51/137 reads (37%) | catalogued as rs1554118091, COSV65373311, COSV65377333; called by muse, mutect2, varscan2
- SMG1 | c.3534T>A p.S1178= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as COSV67175138; called by muse, mutect2, varscan2
- TMEM185A | c.759G>A p.S253= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as rs1159514130; called by muse, mutect2, varscan2
- ZNF496 | c.1299G>A p.K433= | Silent (SNP) | VAF 48/131 reads (37%) | catalogued as rs1207269435, COSV54182773; called by muse, mutect2, varscan2
- MBNL3 | c.1053+768A>T | Intron (SNP) | VAF 65/94 reads (69%) | catalogued as COSV63731893; called by muse, mutect2, varscan2
